CMI case MBCproject_0036 — CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/5ea2bd9e-d7e0-4a96-a28e-acda016cdfe3

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Biospecimens (2 samples)
- Samples MBCproject_0036_T1_RNA, MBCproject_0036_T3_RNA (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
